Surgical pathology report (de-identified scan), TCGA case TCGA-CZ-5984, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Harvard, specimen TCGA-CZ-5984-01A (Primary Tumor).

[page 1 of 6]
PATHOLOGIC DIAGNOSIS:

A. KIDNEY, LEFT NEPHRECTOMY (466 GM):

RENAL CELL CARCINOMA, CLEAR CELL TYPE (4.5 CM)

Fuhrman nuclear grade is III/IV.

Tumor is confined to the kidney.

Renal artery, renal vein, ureteral, and Gerota's fascia margins are negative for tumor.

No adrenal gland is present.

No lymphovascular invasion is identified.

No venous invasion is identified.

Renal artery with calcific atherosclerosis (20% occlusion).

Evaluation of the kidney parenchyma will be performed by the Renal Pathology Service and reported as an addendum.

AJCC (6th edition) stage: pT1b NX MX

B. SPECIMEN LABELED, "REGIONAL LYMPH NODE":

Fibrovascular and adipose tissue with no significant pathologic change.

No lymph node present.

The specimen is entirely submitted for histologic evaluation.

CLINICAL DATA:

History: None given.

Operation: Radical nephrectomy, left.

Clinical Diagnosis: Renal cell cancer.

TISSUE SUBMITTED:

A/1) kidney (lt).

B/2) regional lymph node.

GROSS DESCRIPTION:

The specimen is received fresh, in two parts, each labeled with the patients name and unit number.

Part A received in the frozen section lab, labeled "#1 - lt kidney", and consists of a left radical nephrectomy specimen (466 grams; 18 x 9 x 5.5 cm), to include ureter (3.2 cm in length x 0.5 cm in diameter), renal artery (0.8 cm in length x 0.6 cm in diameter), renal vein (0.6 cm in length x 1.2 cm in diameter) and moderate to abundant attached perinephric fat. Definitive Gerota's fascia is not identified. The kidney (12 x 6.5 x 4.5 cm) is bivalved, revealing a golden yellow, red, tan, focally hemorrhagic, focally gelatinous encapsulated mass (4.5 x 4.0 x 4.0 cm) within the upper pole, which abuts but does not definitively invade through the renal capsule, comes to within 2.3 cm of the renal artery margin, 3.3 cm of the renal vein margin, and 5.5 cm of the ureteral margin. Representative sections of the mass are submitted for cytogenetics and electron microscopy. Additionally, three different areas of the mass (T1, T2, and T3) are submitted to the Tumor Bank with corresponding sections to pathology. The corticomedullary junction is well-defined with tan/pink medullary pyramids. The pelvis displays a tan glistening urothelium and blunting of the calyces. There is a moderate amount of fat within the renal sinus. Moderate to severe atherosclerosis is noted within the renal artery. No lymph nodes are identified within the perinephric fat. Representative sections of the cortex are submitted for electron microscopy and immunofluorescence. Photographs are taken.

[page 2 of 6]
Micro A1: renal vein, renal artery and ureter margins [REDACTED]
frags, ESS.
Micro A2+A3: renal mass at deepest extension, 2 frags total, RSS.
Micro A4: gelatinous/hemorrhagic component of mass, 1 frag, RSS.
Micro A5: mass is relationship to adjacent renal parenchyma, 1 frag,
RSS.
Micro A6: "T1", 1 frag, RSS.
Micro A7: "T2", 1 frag, RSS.
Micro A8: "T3", 1 frag, RSS.
Micro A9: corticomedullary junction, 1 frag, RSS.
Micro A10: pelvis and atherosclerosis of renal artery, 1 frag, RSS.

Part B, labeled "#2 - regional lymph node", and consists of a portion of yellow/red, hemorrhagic adipose tissue (3.6 x 2.2 x 0.8 cm), within which multiple vessels (averaging 1.2 cm in length, ranging from 0.1 cm up to 0.3 cm in diameter) are identified. No lymph nodes are grossly identified.

Micro B1: vessels, multiple frags, [REDACTED]
Micro B2+B3: fat, multiple frags, [REDACTED]
[REDACTED]

ADDENDUM

RENAL PATHOLOGY EVALUATION OF KIDNEY PARENCHYMA

LEFT KIDNEY, NEPHRECTOMY:

DIFFUSE MESANGIAL SCLEROSIS, MILD, MOST LIKELY REPRESENTING AN EARLY
PHASE OF DIABETIC GLOMERULOSCLEROSIS (SEE NOTE)

ARTERIAL AND ARTERIOLAR SCLEROSIS, WITH SUBINTIMAL HYALINOSIS, MODERATE
(SEE NOTE)

MILD CHRONIC CHANGES OF THE PARENCHYMA, INCLUDING:

- FOCAL GLOBAL GLOMERULOSCLEROSIS, MILD (2.2% OF GLOMERULI);
- TUBULAR ATROPHY AND INTERSTITIAL FIBROSIS, MILD (5% OF PARENCHYMA)

NOTE:

The kidney sample examined shows minimal chronic changes, within the expected range for a fifty-one year-old man. There is minimal focal global glomerulosclerosis (2.2% of glomeruli) and minimal tubular atrophy and interstitial fibrosis (5% of the parenchyma). The sample also reveals changes that can probably be attributed to diabetes mellitus (early diffuse diabetic glomerulosclerosis); review of serum glucose level in the system shows several abnormally high values). Signs of active glomerular or interstitial inflammation, or glomerular proliferative lesions are not seen in the sample examined. There is also moderate vascular sclerosis with subintimal hyaline accumulation of the arteriolar vessels.

The kidney parenchyma has been reviewed by [REDACTED], Renal Pathologist.

MICROSCOPIC DESCRIPTION:

Sections of formalin-fixed, paraffin-embedded tissue (block A9) were evaluated using HE, PAS, Jones silver methenamine, and AECG (trichrome) stains.

[page 3 of 6]
Age.

Pathology Report

The sample consists of cortex and medulla. There are 359 glomeruli present, of which 8 (2.2%) are globally sclerosed. The remaining glomeruli show mild to moderate expansion of the mesangial areas by matrix and minimal cellular elements. There are focal double contours in the glomeruli. Other basement membrane defects are not discernible. The interstitium show patchy areas of minimal inflammation by mononuclear cells. Approximately 5% of the cortical parenchyma shows tubular atrophy and interstitial fibrosis. There is an isolated microcyst in the cortex that shows connection with a proximal tubule. The cyst reveals a layer of taller epithelial cells. Arteries and arterioles exhibit moderate sclerosis of the wall with subintimal hyalinosis.

[page 5 of 6]
1

KARYOTYPE: T1:46,XY[10] T2:46,XY[10]
T3;67-74<3n>,XXYY,+3,del(3)(p21)x2,+4,+5,-6,
-9,+10,+11,+12,-13,+16,-18,+20,+21,+22[cp5]/46,XY[4]

METAPHASES COUNTED: 30 ANALYZED: 15 SCORED: 15 BANDING:

INTERPRETATION:

Three parts of this tumor specimen were submitted for cytogenetic analysis. In one part, 5 of 10 metaphases contained clonal aberrations, described above, that included deletion of the short arm of chromosome 3, which is a characteristic finding in renal cell carcinoma, clear cell type. No metaphases were obtained from the other two parts.

COMMENTS:

Mosaicism and small chromosome anomalies may not be detectable using the standard methods employed. Chromosome analysis was performed at a level of 400 bands or greater.

INDICATION FOR TEST:

Kidney Mass

[page 6 of 6]
[REDACTED]

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file dbd2f8e0-d97a-4ff2-b5ab-88859163725e (TCGA-CZ-5984.D9612FED-E194-4538-A4E3-093E5BFECA53.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).